Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5077, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5077-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1:

BONE, 12TH RIB, PARTIAL RESECTION -
BONE AND BONE MARROW WITH NO EVIDENCE OF MALIGNANCY.

PART 2:

KIDNEY, LEFT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR GRADE III/IV, 3.8 CM IN GREATEST DIMENSION.
- B. TUMOR IS CONFINED WITHIN THE RENAL CAPSULE, WITH NO EVIDENCE OF INVASION OF THE RENAL SINUS OR PERI-NEPHRIC ADIPOSE TISSUE.
- C. THERE IS NO EVIDENCE OF ANGIOLYMPHATIC INVASION.
- D. ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- E. NON-NEOPLASTIC KIDNEY WITH MODERATE CHRONIC NEPHROSCLEROSIS.
- F. PATHOLOGIC STAGE: pTNM = pT1a NX MX.
- G. ADRENAL GLAND WITH NO SPECIFIC PATHOLOGIC ABNORMALITY.

Source: NCI Genomic Data Commons file ab281ea9-d2f4-4811-a552-9f2d519ca12f (TCGA-B0-5077.750A7A32-5FB2-4F10-8CC9-3699B8A0E5BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).